Somatic mutation profile of tumor specimen TCGA-CM-6169-01A (aliquot TCGA-CM-6169-01A-11D-1650-10) from TCGA case TCGA-CM-6169, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIA; Age at diagnosis: 67.3 years (24,564 days).
Specimen TCGA-CM-6169-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e3c093b-5301-4f0d-bb36-df9045cf3b81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-6169-10A (Blood Derived Normal), aliquot TCGA-CM-6169-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b5cfaa6-89a4-4398-9625-d4dff85e9dcb

The open-access MAF lists 116 somatic variants for this specimen: 88 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 26, Nonsense Mutation 5, Frame Shift Del 4, Intron 2, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 31/78 reads (40%) | catalogued as rs587779783, CM960067, COSV57322578; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1526G>C p.G509A (on ENST00000288602 / NM_001374244.1; = p.G469A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 134/221 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 45/75 reads (60%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACKR2 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 89/282 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV56176889; called by muse, mutect2, varscan2
- ADAMTS2 | c.3394G>T p.V1132L | Missense Mutation (SNP) | VAF 58/259 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs776650760, COSV99283707; called by muse, mutect2, varscan2
- ADGRE1 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs376031317, COSV51672479; called by muse, mutect2
- APC | c.4602del p.N1535Mfs*30 | Frame Shift Del (DEL) | VAF 53/224 reads (24%) | catalogued as COSV57354744, COSV57394593; called by mutect2, pindel, varscan2
- ASIC1 | c.947C>T p.T316M | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200645931, COSV57316335; called by muse, mutect2, varscan2
- BAIAP3 | c.2354G>A p.R785Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.274); catalogued as rs891288975, COSV50103590, COSV99136171; called by muse, mutect2, varscan2
- CACNA1B | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.482); catalogued as rs777432917, COSV53115276; called by muse, mutect2, varscan2
- CAMSAP3 | c.2354G>A p.R785Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1174342817, COSV50330782, COSV50331150; called by muse, varscan2
- CENPE | c.3046G>C p.D1016H | Missense Mutation (SNP) | VAF 223/569 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.317); catalogued as COSV54376736; called by muse, mutect2, varscan2
- CEP85 | c.419A>C p.H140P | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV53327340; called by muse, mutect2, varscan2
- CRMP1 | c.229C>A p.Q77K | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV61478421; called by muse, mutect2, varscan2
- CYP1A2 | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs368776150; called by muse, mutect2, varscan2
- CYP26B1 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 46/65 reads (71%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs772338043, COSV50010837; called by muse, mutect2, varscan2
- DCUN1D1 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 101/248 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as COSV99489913; called by muse, mutect2, varscan2
- DDX55 | c.1504C>T p.Q502* | Nonsense Mutation (SNP) | VAF 39/90 reads (43%) | catalogued as COSV53015336; called by muse, mutect2, varscan2
- DENND4B | c.2519G>A p.R840H | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); catalogued as rs764671818, COSV63407353; called by muse, mutect2, varscan2
- DIS3L2 | c.476A>T p.N159I | Missense Mutation (SNP) | VAF 106/279 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as COSV56048931; called by muse, mutect2, varscan2
- DLK1 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as rs749760314, COSV57990669; called by muse, mutect2, varscan2
- DMD | c.4282A>T p.K1428* | Nonsense Mutation (SNP) | VAF 36/325 reads (11%) | catalogued as COSV63736727; called by muse, mutect2, varscan2
- DNAH1 | c.12523C>T p.R4175C | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as rs187379693, COSV56233389; called by muse, mutect2, varscan2
- ENPP6 | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV99699115; called by muse, mutect2
- EPB41L5 | c.1990C>T p.R664W | Missense Mutation (SNP) | VAF 220/596 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs538183746, COSV55349347; called by muse, mutect2, varscan2
- ESPL1 | c.5507G>A p.R1836H | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as rs1158817629, COSV54475296; called by muse, mutect2, varscan2
- EXOSC9 | c.557G>A p.S186N | Missense Mutation (SNP) | VAF 94/355 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV54664986; called by muse, mutect2, varscan2
- FAM193A | c.3134G>A p.G1045D | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.079); catalogued as COSV61191209; called by muse, mutect2
- FBN1 | c.5219G>A p.S1740N | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.977); catalogued as COSV57310160; called by muse, mutect2, varscan2
- FGA | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV57393449; called by muse, mutect2, varscan2
- FMN2 | c.449C>A p.A150D | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV60418601; called by muse, mutect2, varscan2
- FMR1 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 633/842 reads (75%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV99503765; called by muse, mutect2, varscan2
- FUT9 | c.235C>A p.L79I | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.838); catalogued as rs1281418434, COSV56142731, COSV56157944; called by muse, mutect2, varscan2
- G3BP1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV62365587; called by muse, mutect2, varscan2
- GGT5 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1026801373, COSV54068813; called by muse, mutect2, varscan2
- GPR89A | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs587773483, COSV58260687; called by muse, mutect2
- ICE1 | c.6032G>A p.R2011H | Missense Mutation (SNP) | VAF 98/170 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs1043116639, COSV56819707, COSV56829871; called by muse, mutect2, varscan2
- ITGB6 | c.921G>T p.L307F | Missense Mutation (SNP) | VAF 121/186 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as COSV51791105, COSV51794815; called by muse, mutect2, varscan2
- KCNH7 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865882613, COSV59783164, COSV59786469; called by muse, mutect2, varscan2
- KCNK2 | c.1258G>T p.A420S (on ENST00000444842 / NM_001017425.3; = p.A405S on NM_014217.4) | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as rs1247856777, COSV67203522, COSV67209077; called by muse, mutect2, varscan2
- KIR2DL1 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 105/146 reads (72%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs779537643, COSV52406976; called by muse, mutect2, varscan2
- LAMA5 | c.9953G>A p.R3318H | Missense Mutation (SNP) | VAF 53/74 reads (72%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1422106752, COSV53353652; called by muse, mutect2, varscan2
- LRIG1 | c.1979C>T p.T660I | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as COSV56237236; called by muse, mutect2, varscan2
- MAB21L2 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1318849042, COSV58260895, COSV58262419; called by muse, mutect2, varscan2
- MAGEA12 | c.744A>C p.Q248H | Missense Mutation (SNP) | VAF 146/358 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.092); catalogued as COSV100756767, COSV63294236; called by muse, varscan2
- MRPL39 | c.342C>A p.D114E | Missense Mutation (SNP) | VAF 107/381 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.891); catalogued as COSV56259951; called by muse, mutect2, varscan2
- MYC | c.327C>A p.D109E (on ENST00000377970; = p.D124E on NM_002467.6) | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99421393; called by muse, mutect2
- MYLK | c.3461C>A p.S1154Y | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60605381, COSV60613414; called by muse, mutect2, varscan2
- NAA15 | c.815A>T p.N272I | Missense Mutation (SNP) | VAF 102/373 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.392); catalogued as COSV56717827; called by muse, mutect2, varscan2
- NPAS4 | c.2066G>T p.W689L | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.281); catalogued as COSV60648995; called by muse, mutect2, varscan2
- NPHS1 | c.3493G>A p.E1165K | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as COSV62286378; called by muse, mutect2, varscan2
- NT5C3B | c.634A>C p.N212H | Missense Mutation (SNP) | VAF 122/421 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV54055025; called by muse, mutect2
- NUDT10 | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62853913; called by muse, mutect2
- OR10G9 | c.714G>T p.Q238H | Missense Mutation (SNP) | VAF 132/404 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66685812; called by muse, mutect2, varscan2
- OR2G3 | c.192C>A p.S64R | Missense Mutation (SNP) | VAF 108/454 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.355); catalogued as COSV100180749; called by muse, mutect2, varscan2
- PAMR1 | c.1557C>A p.D519E (on ENST00000619888 / NM_001001991.3; = p.D536E on NM_015430.4) | Missense Mutation (SNP) | VAF 78/232 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.011); catalogued as rs757650549, COSV53509911, COSV53515622; called by muse, mutect2, varscan2
- PCDHB12 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated, low confidence (0.37); PolyPhen probably damaging (0.925); catalogued as COSV53393478; called by muse, mutect2, varscan2
- POLR1A | c.4345C>T p.R1449* | Nonsense Mutation (SNP) | VAF 118/295 reads (40%) | catalogued as COSV99808348; called by muse, mutect2, varscan2
- PPP4C | c.365A>G p.Q122R | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV99661781; called by muse, mutect2, varscan2
- PRB4 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV54395589; called by muse, varscan2
- PROC | c.1035C>A p.H345Q | Missense Mutation (SNP) | VAF 41/60 reads (68%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV52164898; called by muse, mutect2, varscan2
- PTPRT | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 71/103 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368237025, COSV100626435; called by muse, mutect2, varscan2
- PTX4 | c.1370C>A p.A457D (on ENST00000447419 / NM_001328608.2; = p.A452D on NM_001013658.1) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.034); catalogued as COSV53514012, COSV53514474; called by muse, mutect2, varscan2
- RABL6 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 85/288 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs371358921; called by muse, mutect2, varscan2
- RARS1 | c.45+2T>C p.X15_splice | Splice Site (SNP) | VAF 5/39 reads (13%) | catalogued as COSV99199215; called by muse, mutect2, varscan2
- RHBG | c.764A>G p.Y255C | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV54802093, COSV54808009; called by muse, mutect2, varscan2
- RNASE4 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs771543461, COSV59011502; called by muse, mutect2, varscan2
- SCN5A | c.1742C>T p.S581L | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as rs757945763, COSV61116895; called by muse, mutect2, varscan2
- SDK1 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 61/98 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as rs774307438, COSV67357841; called by muse, mutect2, varscan2
- SEPTIN6 | c.595A>G p.I199V | Missense Mutation (SNP) | VAF 22/394 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.21); catalogued as COSV100595777; called by muse, mutect2
- SLC6A11 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 119/322 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); catalogued as rs757433552, COSV54390218; called by muse, mutect2, varscan2
- SMARCA1 | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 324/410 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100946702; called by muse, varscan2
- SYT6 | c.929G>A p.R310H (on ENST00000610222 / NM_001366225.1; = p.R225H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776030947, COSV65772550; called by muse, mutect2, varscan2
- SZT2 | c.6266C>T p.A2089V (on ENST00000634258 / NM_001365999.1; = p.A2032V on NM_015284.4) | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); catalogued as COSV65167377; called by muse, mutect2, varscan2
- TDRD6 | c.3677T>C p.L1226P | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV60174063, COSV60178188; called by muse, mutect2, varscan2
- TECTA | c.4144G>A p.V1382M | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.119); catalogued as rs199637730, COSV50689122; called by muse, mutect2, varscan2
- TMCO3 | c.626T>A p.V209D | Missense Mutation (SNP) | VAF 108/227 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV64806844, COSV64809400; called by muse, mutect2, varscan2
- TNIP2 | c.388A>G p.M130V | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV100198755; called by muse, mutect2, varscan2
- TRPA1 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 30/349 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV51555915; called by muse, mutect2
- TTN | c.26158A>C p.T8720P (on ENST00000591111; = p.T7793P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/108 reads (60%) | PolyPhen possibly damaging (0.693); catalogued as COSV59904705; called by muse, mutect2, varscan2
- VILL | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as rs1201986478, COSV52182614; called by muse, mutect2, varscan2
- ZMAT3 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.134); catalogued as COSV60992302; called by muse, mutect2, varscan2
- ZMAT4 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.771); catalogued as rs1469992456, COSV52691310; called by muse, mutect2, varscan2
- ZNF497 | c.632C>T p.T211M | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.44); catalogued as rs868535212, COSV54053990; called by muse, mutect2, varscan2
- ZNF540 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.611); catalogued as rs768556407, COSV57107878; called by muse, mutect2, varscan2
- FAT2 | c.11146del p.V3716Ffs*44 | Frame Shift Del (DEL) | VAF 26/129 reads (20%) | called by mutect2, pindel, varscan2
- KCNT2 | c.334del p.A112Hfs*2 | Frame Shift Del (DEL) | VAF 69/364 reads (19%) | called by mutect2, pindel, varscan2
- KRT13 | c.537_538del p.E179Dfs*2 | Frame Shift Del (DEL) | VAF 22/79 reads (28%) | called by pindel, varscan2
- ADAMTS9 | c.3351A>G p.G1117= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV99900118; called by muse, mutect2, varscan2
- ANKFN1 | c.282C>T p.N94= | Silent (SNP) | VAF 62/164 reads (38%) | catalogued as rs201436645, COSV59441624; called by muse, mutect2, varscan2
- APBB3 | c.408G>A p.P136= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs748914035, COSV60051561; called by muse, mutect2, varscan2
- C1QL2 | c.267G>A p.P89= | Silent (SNP) | VAF 35/75 reads (47%) | catalogued as rs751699255, COSV55606037; called by muse, mutect2, varscan2
- CACNA1E | c.2055G>T p.V685= | Silent (SNP) | VAF 136/363 reads (37%) | catalogued as COSV62383560; called by muse, mutect2, varscan2
- COL26A1 | c.519G>A p.P173= (on ENST00000313669 / NM_001278563.3; = p.P171= on NM_133457.4) | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as rs559355283, COSV100562015; called by muse, mutect2, varscan2
- DDR1 | c.2413C>T p.L805= (on ENST00000324771; = p.L768= on NM_001954.4) | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as COSV61319391; called by muse, mutect2, varscan2
- DHRS2 | c.636C>T p.C212= | Silent (SNP) | VAF 34/133 reads (26%) | catalogued as COSV51630587; called by muse, mutect2, varscan2
- DOK7 | c.870G>A p.S290= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as rs149019681; called by muse, varscan2
- GNL2 | c.1773C>T p.N591= | Silent (SNP) | VAF 70/556 reads (13%) | catalogued as rs200495851, COSV56170839; called by mutect2, varscan2
- GOLGB1 | c.7254C>T p.S2418= | Silent (SNP) | VAF 97/314 reads (31%) | catalogued as COSV100511479; called by muse, mutect2, varscan2
- GRM6 | c.1389C>T p.N463= | Silent (SNP) | VAF 33/70 reads (47%) | catalogued as rs139745015; called by muse, mutect2, varscan2
- GRM7 | c.1995T>C p.G665= | Silent (SNP) | VAF 90/263 reads (34%) | catalogued as COSV100738331, COSV63131393; called by muse, mutect2, varscan2
- KSR1 | c.1662C>T p.D554= (on ENST00000644974 / NM_001367810.1; = p.D439= on NM_014238.2) | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs373150357; called by muse, mutect2, varscan2
- MAN2B2 | c.2436C>T p.N812= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as rs771391808, COSV53450798; called by muse, mutect2, varscan2
- MS4A8 | c.27G>T p.P9= | Silent (SNP) | VAF 37/342 reads (11%) | catalogued as COSV55753239; called by muse, mutect2, varscan2
- OR4X2 | c.639C>A p.I213= | Silent (SNP) | VAF 182/536 reads (34%) | catalogued as COSV56582368; called by muse, mutect2, varscan2
- OTOP2 | c.285C>T p.D95= | Silent (SNP) | VAF 37/112 reads (33%) | catalogued as rs762709751, COSV58880760; called by muse, mutect2, varscan2
- PSD4 | c.3166C>T p.L1056= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs1451830338, COSV55524715; called by muse, mutect2, varscan2
- ROBO2 | c.3666C>T p.D1222= | Silent (SNP) | VAF 59/167 reads (35%) | catalogued as rs201339466; called by muse, mutect2, varscan2
- SACS | c.6876G>T p.L2292= | Silent (SNP) | VAF 171/382 reads (45%) | catalogued as COSV66535053; called by muse, mutect2, varscan2
- SEC13 | c.630G>A p.A210= (on ENST00000350697 / NM_183352.3; = p.A213= on NM_030673.4) | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as rs138539081; called by muse, mutect2, varscan2
- SH2D7 | c.882C>A p.G294= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV51947603; called by muse, mutect2, varscan2
- TNXB | c.8253C>T p.D2751= (on ENST00000647633; = p.D2504= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/139 reads (43%) | catalogued as rs1042037638, COSV64474217; called by muse, mutect2, varscan2
- ZIC4 | c.786G>A p.K262= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV67170770; called by muse, mutect2, varscan2
- ZNF251 | c.1629C>T p.H543= | Silent (SNP) | VAF 94/437 reads (22%) | catalogued as rs781553257, COSV52956379; called by muse, mutect2, varscan2
- KALRN | c.4929+22006G>A | Intron (SNP) | VAF 63/171 reads (37%) | catalogued as rs1271817050, COSV53762954; called by muse, mutect2, varscan2
- OFCC1 | n.393-2895G>A | Intron (SNP) | VAF 72/311 reads (23%) | catalogued as rs766641614; called by muse, mutect2, varscan2
